Somatic mutation profile of tumor specimen MMRF_1845_1_BM_CD138pos (aliquot MMRF_1845_1_BM_CD138pos_T1_KBS5U_L05775) from MMRF case MMRF_1845, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.6 years (17,031 days).
Specimen MMRF_1845_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a536d06-701a-4139-88ad-8f1dfc5e48e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1845_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1845_1_PB_Whole_C3_KBS5U_L05800; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce998d9e-49c3-4a96-b4e5-f2d27aca64aa

The open-access MAF lists 183 somatic variants for this specimen: 66 protein-altering or splice-affecting, 27 silent, 90 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, 3'UTR 46, Silent 27, Intron 18, 3'Flank 9, 5'UTR 9, 5'Flank 7, Nonsense Mutation 4, Splice Region 3, In Frame Del 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG1 | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as rs1406129471, COSV59203758; called by muse, mutect2, varscan2
- ALOXE3 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as rs1230050207, COSV59077787; called by muse, mutect2, varscan2
- CCDC141 | c.2180G>A p.W727* | Nonsense Mutation (SNP) | VAF 37/111 reads (33%) | catalogued as rs1422829493, COSV55369906; called by muse, mutect2, varscan2
- CHML | c.974A>T p.Y325F | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV100087045; called by muse, mutect2
- CLDND2 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99389875; called by muse, mutect2, varscan2
- CXCL5 | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV56018482; called by muse, mutect2, varscan2
- ETNK2 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV65819996; called by muse, mutect2, varscan2
- FAM171A1 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV65315971; called by muse, mutect2
- FRMD3 | c.1610G>A p.G537E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1312602772; called by muse, mutect2
- HSPA6 | c.1677C>G p.S559R | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs1213260056; called by muse, mutect2
- IGHV2-70 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 56/80 reads (70%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs373084365; called by muse, varscan2
- IGLV5-45 | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs773575221; called by muse, varscan2
- IL17RD | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.181); catalogued as rs374629547; called by muse, mutect2
- MAGEB4 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1470097855, COSV64396948, COSV64397555; called by muse, mutect2, varscan2
- METTL9 | c.358T>C p.L120= | Splice Region (SNP) | VAF 28/63 reads (44%) | catalogued as rs764391674; called by muse, mutect2, varscan2
- MMRN1 | c.1868A>C p.E623A | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as rs1326769111; called by muse, mutect2, varscan2
- NSUN4 | c.94-7C>G | Splice Region (SNP) | VAF 6/73 reads (8%) | catalogued as rs1483714520; called by muse, mutect2
- OR2G2 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs200433328, COSV60740485; called by muse, mutect2, varscan2
- PYHIN1 | c.625A>C p.I209L | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV63724268; called by muse, mutect2, varscan2
- SPINT1 | c.1216C>T p.R406C (on ENST00000344051 / NM_181642.3; = p.R390C on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777340322; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 5/52 reads (10%) | PolyPhen benign (0.022); catalogued as rs865914042; called by muse, mutect2
- TPP1 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs549928656; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPR | c.5950G>A p.E1984K | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); catalogued as COSV66599554; called by muse, mutect2
- VWDE | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs950123088, COSV51719484; called by muse, mutect2, varscan2
- ZNF257 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 31/70 reads (44%) | catalogued as COSV71312573; called by muse, mutect2, varscan2
- ACACA | c.3947A>T p.K1316M | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2
- ADRA1B | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- AK9 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- APBB1 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARID5B | c.1421A>C p.E474A | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ASB9 | c.151dup p.S51Ffs*25 | Frame Shift Ins (INS) | VAF 31/72 reads (43%) | called by mutect2, pindel, varscan2
- BMPR1B | c.1019T>C p.V340A | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CEP250 | c.6585G>A p.M2195I | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- COQ8B | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- CPB2 | c.62T>C p.F21S | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD1 | c.4763C>A p.T1588N (on ENST00000520002; = p.T1587N on NM_033225.6) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DZIP1L | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- FIGNL2 | c.427C>A p.L143I | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2
- FMN2 | c.4838T>A p.M1613K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGHV1-69D | c.235T>A p.Y79N | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, varscan2
- IGHV1-69D | c.234C>G p.N78K | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, varscan2
- JAKMIP2 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LNX1 | c.57_80del p.Q19_N26del | In Frame Del (DEL) | VAF 51/125 reads (41%) | called by mutect2, pindel, varscan2
- LRCH1 | c.380T>G p.L127R | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MIER1 | c.424C>T p.Q142* (on ENST00000355356 / NM_001077701.3; = p.Q159* on NM_020948.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 39/140 reads (28%) | called by muse, mutect2, varscan2
- MLLT10 | c.1417_1420del p.Q473Vfs*31 | Frame Shift Del (DEL) | VAF 64/122 reads (52%) | called by mutect2, pindel, varscan2
- NFATC4 | c.2666T>C p.L889P | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PARS2 | c.769C>G p.H257D | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PIP5K1A | c.745C>T p.P249S (on ENST00000368888 / NM_001135638.2; = p.P236S on NM_003557.3) | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- RAP1GAP2 | c.*29A>G | Splice Region (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- ROBO2 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RPS6KA6 | c.370A>T p.R124W | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RRAGC | c.1196T>C p.I399T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SGO2 | c.3289G>A p.E1097K | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SLC5A12 | c.1798G>T p.G600C | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2
- SPATA4 | c.657G>T p.L219F | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); called by muse, mutect2
- SYMPK | c.1940T>A p.I647N | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.017); called by muse, mutect2
- SYNPO2 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TENM1 | c.7043A>G p.D2348G | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM1 | c.6808T>A p.F2270I | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TMEM145 | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TTC3 | c.1233+2T>C p.X411_splice | Splice Site (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- USH2A | c.3685T>G p.L1229V | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- USP26 | c.1798C>A p.P600T | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- WDFY3 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZDHHC4 | c.991T>G p.F331V | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- ACOXL | c.1086A>T p.S362= | Silent (SNP) | VAF 29/115 reads (25%) | called by muse, mutect2, varscan2
- B3GALT6 | c.645C>T p.G215= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs1354160280; called by muse, mutect2, varscan2
- CACNA1G | c.4869G>T p.L1623= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- CDH3 | c.2340C>T p.F780= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as rs1425381774, COSV50583750; ClinVar: uncertain significance; called by muse, mutect2
- CES2 | c.450G>A p.A150= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs745571678, COSV57697223; called by mutect2, varscan2
- DNAJA1 | c.852C>T p.T284= | Silent (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- EDA2R | c.618G>A p.E206= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs898585172; called by muse, mutect2, varscan2
- GABRE | c.1419C>G p.L473= | Silent (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- GPR139 | c.402C>G p.L134= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs1165448572; called by muse, varscan2
- HID1 | c.1839C>G p.L613= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- HTR4 | c.786C>T p.C262= | Silent (SNP) | VAF 47/112 reads (42%) | called by muse, mutect2, varscan2
- MAGEC1 | c.1569G>T p.G523= | Silent (SNP) | VAF 9/135 reads (7%) | catalogued as COSV53580606; called by muse, mutect2
- MAN2A2 | c.3294A>G p.Q1098= | Silent (SNP) | VAF 30/103 reads (29%) | called by muse, mutect2, varscan2
- MYO1C | c.2382C>T p.F794= (on ENST00000648651 / NM_001080779.2; = p.F759= on NM_033375.5) | Silent (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- NFIX | c.1260C>T p.N420= (on ENST00000592199 / NM_001365902.3; = p.N428= on NM_001271043.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV62181765; called by muse, mutect2, varscan2
- PNLIPRP3 | c.696C>T p.T232= | Silent (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- POLN | c.774C>T p.G258= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV67024785; called by muse, mutect2, varscan2
- PTPRB | c.4236C>T p.I1412= | Silent (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- SETD1B | c.4098C>T p.L1366= | Silent (SNP) | VAF 38/87 reads (44%) | called by muse, mutect2, varscan2
- SLC22A7 | c.108C>G p.L36= | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- SNURF | c.126G>C p.P42= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV57594825; called by muse, mutect2, varscan2
- SPTB | c.2574C>T p.D858= | Silent (SNP) | VAF 44/132 reads (33%) | catalogued as rs1293691630, COSV101072344; called by muse, mutect2, varscan2
- TMEFF2 | c.933T>C p.V311= | Silent (SNP) | VAF 45/94 reads (48%) | called by muse, mutect2, varscan2
- TRIML1 | c.159T>C p.C53= | Silent (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- TTN | c.38749C>T p.L12917= (on ENST00000591111; = p.L5493= on NM_003319.4) | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- ZBTB8OS | c.36C>T p.V12= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as COSV59386005; called by muse, mutect2
- ZNF462 | c.4260C>T p.S1420= | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as rs1261320614, COSV52938554, COSV52941065; called by muse, mutect2, varscan2
- ABCC9 | c.406+2602T>A | Intron (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- ABI2 | c.*4675A>T | 3'UTR (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- ABLIM3 | c.-143G>A | 5'UTR (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2, varscan2
- AC241929.1 | chr1:146857735 C>A | 3'Flank (SNP) | VAF 51/94 reads (54%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501832 del TTTATTAAAGGGGAGGGGCAAA | 5'Flank (DEL) | VAF 8/106 reads (8%) | called by mutect2, pindel
- ASB2 | c.*10C>T | 3'UTR (SNP) | VAF 6/48 reads (13%) | catalogued as rs201042901; called by muse, mutect2, varscan2
- BEAN1 | c.-6G>A | 5'UTR (SNP) | VAF 6/40 reads (15%) | catalogued as rs1420302457; called by muse, mutect2
- BICC1 | c.*2512A>C | 3'UTR (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- BMERB1 | chr16:15434518 G>A | 5'Flank (SNP) | VAF 4/51 reads (8%) | called by muse, mutect2
- CACNA2D1 | chr7:81946686 C>A | 3'Flank (SNP) | VAF 35/74 reads (47%) | called by muse, mutect2, varscan2
- CAMK4 | c.*9404G>T | 3'UTR (SNP) | VAF 6/70 reads (9%) | catalogued as rs1018471365; called by muse, mutect2
- CASP14 | c.404-99C>A | Intron (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- CCDC171 | c.*642C>G | 3'UTR (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- CCL28 | c.*2381G>A | 3'UTR (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- CCND3 | c.*544C>T | 3'UTR (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- CFAP47 | c.2844+258G>A | Intron (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- CHRM2 | chr7:137020022 C>T | 3'Flank (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- CLCN5 | chrX:50093830 A>G | 3'Flank (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- CLIP1 | c.*593G>A | 3'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- CNNM1 | c.2340+67G>A | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- COLGALT2 | c.1137-721T>A | Intron (SNP) | VAF 41/74 reads (55%) | called by muse, mutect2, varscan2
- CYSLTR1 | c.*801A>T | 3'UTR (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- DFFB | c.*694C>T | 3'UTR (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- DIPK2B | c.499-4781T>C | Intron (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- EMSY | chr11:76552359 G>T | 3'Flank (SNP) | VAF 37/77 reads (48%) | called by muse, mutect2, varscan2
- EPS15 | c.561+3198C>T | Intron (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2, varscan2
- ERGIC3 | c.685+81G>A | Intron (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- FAM135B | c.3282-43G>A | Intron (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- FAM83A | c.*1676_*1683del | 3'UTR (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel
- FANCC | c.687-15A>G | Intron (SNP) | VAF 7/64 reads (11%) | catalogued as rs765327075; called by muse, mutect2, varscan2
- FARP1 | c.*2113G>C | 3'UTR (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- FOSL2 | c.-155C>T | 5'UTR (SNP) | VAF 3/36 reads (8%) | catalogued as rs1405235385; called by muse, mutect2
- GMCL1 | c.*620dup | 3'UTR (INS) | VAF 32/72 reads (44%) | catalogued as rs1225714896; called by mutect2, varscan2
- GUCY1A2 | c.*2075G>A | 3'UTR (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- IGLC2 | c.*9C>T | 3'UTR (SNP) | VAF 42/198 reads (21%) | catalogued as rs778709417; called by muse, mutect2
- KCND2 | c.-443C>T | 5'UTR (SNP) | VAF 41/125 reads (33%) | called by muse, mutect2, varscan2
- KCNJ5 | chr11:128919575 C>T | 3'Flank (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- KLF14 | c.*309A>G | 3'UTR (SNP) | VAF 3/41 reads (7%) | catalogued as COSV100205919; called by muse, mutect2
- KLHL14 | c.-44+516_-44+518del | Intron (DEL) | VAF 5/43 reads (12%) | catalogued as rs780568428; called by mutect2, pindel
- LGI3 | chr8:22156974 G>C | 5'Flank (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- LINC02346 | n.62G>A | RNA (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- LPP | c.1240+1523A>G | Intron (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- LPXN | c.*488C>G | 3'UTR (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- LRRK2 | c.*229A>G | 3'UTR (SNP) | VAF 23/40 reads (58%) | catalogued as rs200343036; called by muse, mutect2, varscan2
- LUC7L3 | c.*33+299_*33+303del | Intron (DEL) | VAF 52/98 reads (53%) | catalogued as rs1251540599; called by pindel, varscan2
- MARCHF7 | c.*633G>A | 3'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- MFAP3L | c.*1687G>A | 3'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- MID1 | c.*1955T>A | 3'UTR (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- MS4A4A | c.*608G>A | 3'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- MXD1 | c.*4320T>G | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2
- NECTIN1 | c.*2741A>T | 3'UTR (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- NOX4 | chr11:89491541 C>T | 5'Flank (SNP) | VAF 31/66 reads (47%) | catalogued as rs944418009; called by muse, mutect2, varscan2
- NUP98 | c.*609T>C | 3'UTR (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- OR5T1 | c.-113A>G | 5'UTR (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- OTUD3 | c.*2649T>A | 3'UTR (SNP) | VAF 16/28 reads (57%) | catalogued as rs911164666; called by muse, mutect2, varscan2
- PCDH11X | c.*1981G>C | 3'UTR (SNP) | VAF 51/114 reads (45%) | called by muse, mutect2, varscan2
- PFDN5 | c.175+29A>C | Intron (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- PLEKHF2 | c.*306G>A | 3'UTR (SNP) | VAF 24/74 reads (32%) | catalogued as rs111482529, COSV100193360; called by muse, mutect2, varscan2
- PLSCR1 | c.*373A>G | 3'UTR (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- POU3F2 | c.*1018del | 3'UTR (DEL) | VAF 14/61 reads (23%) | catalogued as COSV60409806; called by mutect2, pindel, varscan2
- PYCR2 | c.*385G>A | 3'UTR (SNP) | VAF 45/131 reads (34%) | called by muse, mutect2, varscan2
- QRFPR | c.*62G>C | 3'UTR (SNP) | VAF 11/64 reads (17%) | catalogued as rs13107938; called by muse, mutect2, varscan2
- RCAN1 | c.*1466C>T | 3'UTR (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- RCC2 | chr1:17407816 C>T | 3'Flank (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- RIMS2 | chr8:104254980 C>T | 3'Flank (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- RIMS2 | chr8:104255895 C>T | 3'Flank (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- RORB-AS1 | n.886+315G>A | Intron (SNP) | VAF 7/127 reads (6%) | catalogued as COSV100974665; called by muse, mutect2
- SEL1L | c.*5311T>A | 3'UTR (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- SH2D5 | c.*1634C>A | 3'UTR (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- SLC6A3 | c.*808C>T | 3'UTR (SNP) | VAF 21/62 reads (34%) | catalogued as rs747708228, COSV54361740, COSV54365395; called by muse, varscan2
- SNU13 | chr22:41693755 C>G | 5'Flank (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- SOX2 | c.*274A>G | 3'UTR (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- SPACA7 | c.*5G>A | 3'UTR (SNP) | VAF 6/20 reads (30%) | catalogued as rs568926596, COSV99366924; called by muse, mutect2, varscan2
- TAFA5 | c.112+49486G>A | Intron (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- TARS3 | c.-73C>T | 5'UTR (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- TEAD1 | c.*354A>C | 3'UTR (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- TFAP2D | c.-57T>C | 5'UTR (SNP) | VAF 39/79 reads (49%) | catalogued as rs912134437, COSV50437658, COSV99145737, COSV99145767; called by muse, mutect2, varscan2
- THBS2 | c.*1810G>A | 3'UTR (SNP) | VAF 31/63 reads (49%) | catalogued as rs1440269992; called by muse, mutect2
- THBS4 | c.2266-43G>T | Intron (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- TK2 | c.*102C>T | 3'UTR (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- TMEM71 | c.*106G>A | 3'UTR (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- TNFRSF12A | c.94+34C>A | Intron (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- TNFRSF1A | c.*32G>A | 3'UTR (SNP) | VAF 18/36 reads (50%) | catalogued as COSV99164379; called by muse, mutect2, varscan2
- TOMM40L | c.-22C>G | 5'UTR (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- WIPI2 | c.*1036A>C | 3'UTR (SNP) | VAF 42/86 reads (49%) | called by muse, mutect2, varscan2
- WWC3 | c.*1587T>G | 3'UTR (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- ZC3HAV1 | c.-263C>T | 5'UTR (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- ZFP30 | c.*2493G>T | 3'UTR (SNP) | VAF 18/60 reads (30%) | catalogued as rs886490417; called by muse, mutect2, varscan2
- ZNF22 | chr10:45000131 C>G | 5'Flank (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- ZNF687 | chr1:151281829 C>T | 5'Flank (SNP) | VAF 9/186 reads (5%) | called by muse, mutect2
